Somatic mutation profile of tumor specimen TCGA-M7-A725-01A (aliquot TCGA-M7-A725-01A-12D-A32B-08) from TCGA case TCGA-M7-A725, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.1 years (20,474 days).
Specimen TCGA-M7-A725-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2986032f-dae0-4407-9290-b1b8394421de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-M7-A725-10A (Blood Derived Normal), aliquot TCGA-M7-A725-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0255fed6-885f-432e-ae08-f7f693ef09a7

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 20, Silent 4, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 24/35 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV61683964, COSV61688596, COSV61694890; called by muse, mutect2, varscan2
- ADAMTS13 | c.4004C>T p.A1335V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99390250, COSV99390432; called by muse, mutect2, varscan2
- ATM | c.5537T>A p.I1846N | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99591592; called by muse, mutect2, varscan2
- CCDC186 | c.159A>T p.L53F | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV100991048; called by muse, mutect2, varscan2
- CD40LG | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 52/64 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs1350282799, COSV65699086; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD3 | c.6442+2T>C p.X2148_splice (on ENST00000297405 / NM_001363185.1; = p.X2044_splice on NM_052900.3) | Splice Site (SNP) | VAF 32/146 reads (22%) | catalogued as COSV99845840; called by muse, mutect2, varscan2
- EPOR | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139756642; called by muse, mutect2, varscan2
- LRP4 | c.3320G>A p.R1107H | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs750691101, COSV101066836; called by muse, mutect2
- MAP3K9 | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101173749; called by muse, mutect2, varscan2
- NTNG2 | c.920G>T p.C307F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100647688; called by muse, mutect2
- PI4KA | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as rs1456231561, COSV99748309; called by muse, mutect2, varscan2
- PKHD1L1 | c.308G>A p.R103K | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV101006740; called by muse, varscan2
- RCC2 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs866954648, COSV64905188; called by muse, mutect2
- SATB2 | c.630T>A p.Y210* | Nonsense Mutation (SNP) | VAF 34/80 reads (43%) | catalogued as COSV99612435; called by muse, mutect2, varscan2
- SLC37A4 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.051); catalogued as rs1200051701, COSV100421613, COSV58155801; called by muse, mutect2, varscan2
- TMEM132B | c.2719G>A p.V907I | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751942292, COSV54747583; called by muse, mutect2, varscan2
- TMTC4 | c.2153C>T p.T718M (on ENST00000376234 / NM_001350577.2; = p.T737M on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1337743287, COSV100168859; called by muse, mutect2
- TTN | c.17406T>A p.N5802K (on ENST00000591111; = p.N4875K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | PolyPhen benign (0); catalogued as COSV100627005; called by muse, varscan2
- VPS13D | c.2126T>A p.V709E | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV99169254; called by muse, mutect2, varscan2
- WDR49 | c.1059C>G p.D353E (on ENST00000308378 / NM_001366158.1; = p.D694E on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100393719; called by muse, mutect2
- YY2 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 137/159 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63411106; called by muse, mutect2, varscan2
- ZNF548 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 146/388 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100278278; called by muse, mutect2, varscan2
- ABHD8 | c.774C>T p.C258= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV99917349; called by muse, mutect2
- ADAMTS5 | c.612G>A p.P204= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1205611997, COSV53184670; called by muse, mutect2, varscan2
- IRF4 | c.549G>A p.P183= | Silent (SNP) | VAF 51/118 reads (43%) | catalogued as rs200431511; called by muse, mutect2, varscan2
- PROM1 | c.954C>T p.S318= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV71699995; called by muse, mutect2, varscan2
